Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A8MG, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A8MG-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Patient Name

Med. Rec. #:

DOB:

Soc. Sec. #:

Physician(s):

Visit #:

Sex: Male

Location:

Accession #:

Service Date:

Received:

Client:

ICD-O-3

Adenocarcinoma NOS 8140/3

Site: Prostate NOS C61.9

9/11/2014

FINAL PATHOLOGIC DIAGNOSIS

A. Prostate and seminal vesicles, prostatectomy:

- Prostate: Prostatic adenocarcinoma, Gleason grade 3+4 (+5) (score = 7) with focal extraprostatic extension and a positive margin at the left apex; see comment.
- Right seminal vesicle: Prostatic adenocarcinoma growing around seminal vesicle and extending very near to the inked surfaces.
- Left seminal vesicle: Prostatic adenocarcinoma growing around seminal vesicle and extending very near to the inked surfaces.

B. Anterior bladder neck, biopsy: Benign muscle and fibroadipose tissue, no evidence of carcinoma.

COMMENT:

Synoptic Comment for Prostate Tumors

1. Type of tumor: Small acinar adenocarcinoma.
2. Location of tumor: Left posterior apex (slide A2), left posterior mid gland (slides A10-A13), left anterior apex (slide A2), left anterior mid gland (slides A14-A16), right posterior mid gland (slides A6-A9), right anterior mid gland (slides A3-A5), right seminal vesicle (slide A19), left seminal vesicle (slide A20).
3. Estimated volume of tumor: 4.2 cubic cm.
4. Gleason score: 3+4, primary pattern 3, secondary pattern 4.
Note that there is a small component of Gleason pattern 5 scattered throughout the prostate, most notably in the right posterior mid gland (slide A8) and the left posterior mid gland (slide A12).
5. Estimated volume > Gleason pattern 3: 40%.
6. Involvement of capsule: Tumor invades capsule, right posterior mid gland, (slide A7), left posterior mid gland (slide A11).
7. Extraprostatic extension: Extraprostatic extension present, limited in extent (left seminal vesicle prostatic junction, slide A20).
8. Status of excision margins for tumor: Tumor extends to inked excision margins, left apex (slide

[page 2 of 3]
A2); and tumor extends very close to the bilateral posterior seminal vesicle margins (slides A19 and A20).

Status of excision margins for benign prostate glands: Benign glands present at inked excision margins (right and left bladder margins, slides A17 and A18).

9. Involvement of seminal vesicle: Present, both sides (slides A19 and A20).

10. Perineural infiltration: Present, extensive.

11. Prostatic intraepithelial neoplasia (PIN): Present, extensive.

12. AJCC/UICC stage: pT3bNXMX.

13. Additional comments: The prostatic adenocarcinoma in this case consists predominantly of Gleason patterns 3 and 4 with focal areas of grade 5 present. The prostate is extensively involved, adenocarcinoma is present in all histologic sections examined except the right apex and bladder margins. Tumor extends to the left apical margin and tumor involves the seminal vesicles, bilaterally. In addition, there is a focus of lymphovascular invasion in the right posterior mid gland (slide A13).

These results were discussed with [REDACTED]

Specimen(s) Received

A: Prostate and seminal vesicles (fresh)

B: Anterior bladder neck

Clinical History

The patient is a [REDACTED] man with a history of bilateral prostate cancer, Gleason grade 3+4=7 ([REDACTED]), who now undergoes robotic-assisted laparoscopic total prostatectomy. Per the operative note, there is no lymph node tissue, or fatty tissue in the obturator fossa or overlying external iliac veins, so a lymph node dissection is not performed.

Gross Description

The specimen is received in two parts, each labeled with the patient's name and medical record number.

Part A, received fresh and labeled "prostate and seminal vesicles," consists of a 29 gm radical prostatectomy specimen measuring 3.1 cm from superior to inferior, 4.5 cm from medial to lateral, and 2.4 cm from anterior to posterior, containing an unremarkable left seminal vesicle (3.0 x 1.1 x 0.5 cm), right seminal vesicle (3.0 x 1.7 x 0.9 cm), left vas deferens (2.5 x 0.6 cm), and right vas deferens (2.3 x 0.6 cm). A portion of the tumor is taken for tissue banking purposes from the left and right posterior mid gland. The specimen is then glued together and is fixed overnight. After fixation, the apex and base urethral margins are removed, and the specimen is transversely sectioned from apex to base into eight slices. There are suspicious tan-white nodules in the left posterior mid gland (slice 4) and the left and right posterior mid glands (slice 6). The nodules do not appear to involve the seminal vesicles, and do not involve any of the specimen margins. The surface of the prostate gland is somewhat roughened and contains numerous metal surgical clips. The left prostate is inked blue, the right green, and the deep, black. Representative sections are submitted as follows:

Apical margins

Cassette A1: Right apex, 12 - 6 o'clock, radially sectioned and entirely submitted.

Cassette A2: Left apex, 12 - 6 o'clock, radially sectioned and entirely submitted.

Right anterior quadrant

Cassette A3: Serial slice 2.

Cassette A4: Serial slice 4.

Cassette A5: Serial slice 6.

Right posterior quadrant

Cassette A6: Serial slice 2.

Cassette A7: Serial slice 4.

Cassette A8: Serial slice 6.

Cassette A9: Serial slice 8.

Left posterior quadrant

Cassette A10: Serial slice 2.

Cassette A11: Serial slice 4.

Cassette A12: Serial slice 6.

[page 3 of 3]
Cassette A13: Serial slice 8.

Left anterior quadrant

Cassette A14: Serial slice 2.

Cassette A15: Serial slice 4.

Cassette A16: Serial slice 6.

Bladder margins

Cassette A17: Right bladder margin, bread-loafed and entirely submitted.

Cassette A18: Left bladder margin, bread-loafed and entirely submitted.

Prostatic/seminal vesicle junction

Cassette A19: Right seminal vesicle and cross-section of vas deferens.

Cassette A20: Left seminal vesicle and cross-section of vas deferens.

Part B, received in formalin and labeled "anterior bladder neck," consists of three pieces of cauterized, unoriented, tan-brown soft tissue measuring 3.1 x 2.9 x 0.7 cm in aggregate. The unoriented pieces are inked black, sectioned, and entirely submitted in cassettes B1-B2.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Electronically signed out

Source: NCI Genomic Data Commons file a310c24b-fb03-4bcb-bfc7-d7e5e7e4718a (TCGA-V1-A8MG.6E6ED2C5-9591-41BD-A910-F5E1A8637159.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).